Somatic mutation profile of cancer-model specimen HCM-BROD-0648-C71-85R (Adherent Cell Line, passage 8; aliquot HCM-BROD-0648-C71-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0648-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,260 days).
Specimen HCM-BROD-0648-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ca7768-7f68-4f2b-8784-27c5ed2cc556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0648-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0648-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7957c55f-e6e5-4a00-80c4-4916d1a84fc7

The open-access MAF lists 7,111 somatic variants for this specimen: 4,469 protein-altering or splice-affecting, 2,342 silent, 300 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,114, Silent 2,342, Intron 182, Nonsense Mutation 180, Splice Site 85, Splice Region 74, 3'UTR 31, 5'UTR 29, 5'Flank 28, 3'Flank 20, RNA 9, Frame Shift Del 8.

Variants (750 of 7,111; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDA | c.396+1G>A p.X132_splice | Splice Site (SNP) | VAF 263/590 reads (45%) | catalogued as rs727504537, COSV58876916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYS | c.7793G>A p.G2598D | Missense Mutation (SNP) | VAF 219/494 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs527236064, CM121440; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRID2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 117/464 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs368143665, COSV56207880; ClinVar: likely pathogenic; called by muse, varscan2
- MSH6 | c.2910G>A p.W970* | Nonsense Mutation (SNP) | VAF 313/666 reads (47%) | catalogued as rs765411990, COSV52286399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEB | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 154/334 reads (46%) | catalogued as rs1553548666, CM1513203, COSV99428271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 42/237 reads (18%) | catalogued as rs746824139, CM992365, CX1512904, COSV62195847; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 311/431 reads (72%) | catalogued as rs786204884, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC26A4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1562822565, CM011489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 142/607 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 125/598 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1553857889, COSV53197508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 99/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735822; called by muse, mutect2, varscan2
- AAK1 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV68642789; called by muse, mutect2, varscan2
- AASS | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 299/966 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750821357; called by muse, mutect2, varscan2
- ABCA6 | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 89/529 reads (17%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.781); catalogued as rs949014311; called by muse, varscan2
- ABCB11 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 165/355 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1403850332, COSV55601803; called by muse, varscan2
- ABCC11 | c.2475G>A p.W825* | Nonsense Mutation (SNP) | VAF 218/452 reads (48%) | catalogued as rs750609137, COSV62322921; called by muse, mutect2, varscan2
- ABCC4 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100972546; called by muse, mutect2, varscan2
- ABCC9 | c.1914G>A p.Q638= | Splice Region (SNP) | VAF 63/322 reads (20%) | catalogued as rs565125768, COSV53966281, COSV53988533; called by muse, mutect2, varscan2
- ABHD6 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750011197; called by muse, varscan2
- ABHD6 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241505909; called by muse, varscan2
- ABI3BP | c.2483G>A p.S828N | Missense Mutation (SNP) | VAF 281/627 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs745918552; called by muse, mutect2, varscan2
- ABL2 | c.2924C>T p.P975L (on ENST00000502732 / NM_007314.4; = p.P960L on NM_005158.5) | Missense Mutation (SNP) | VAF 191/776 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746054653; called by muse, mutect2, varscan2
- ABLIM3 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 98/537 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV58643438; called by muse, mutect2, varscan2
- ABTB2 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 110/544 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as rs1449069487, COSV54397364; called by muse, varscan2
- ABTB2 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 190/985 reads (19%) | catalogued as rs1239067377; called by muse, mutect2, varscan2
- AC005697.1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 170/716 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs535087199; called by muse, varscan2
- AC011005.1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 397/1220 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs540175247, COSV71956058; called by muse, mutect2, varscan2
- AC015802.6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/314 reads (13%) | SIFT deleterious, low confidence (0); catalogued as rs1489253007; called by muse, mutect2, varscan2
- AC093827.5 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 81/515 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1198516272; called by muse, mutect2, varscan2
- AC233723.1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 149/656 reads (23%) | PolyPhen possibly damaging (0.711); catalogued as rs576280890; called by muse, mutect2, varscan2
- ACAA2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 113/464 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV53271010; called by muse, mutect2, varscan2
- ACADS | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 164/660 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747339462, CM035802; called by muse, mutect2
- ACBD4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 71/496 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs773910896; called by muse, varscan2
- ACD | c.329C>T p.S110F (on ENST00000620338; = p.S24F on NM_022914.3) | Missense Mutation (SNP) | VAF 91/739 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs771660128; called by muse, mutect2, varscan2
- ACE | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 266/552 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52012879; called by muse, mutect2, varscan2
- ACHE | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 178/1273 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs913768027; called by mutect2, varscan2
- ACP3 | c.966G>A p.K322= | Splice Region (SNP) | VAF 55/273 reads (20%) | catalogued as rs761207057; called by muse, mutect2, varscan2
- ACSM2A | c.733G>A p.D245N (on ENST00000219054; = p.D166N on NM_001308169.2) | Missense Mutation (SNP) | VAF 134/148 reads (91%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.783); catalogued as rs1197928623, COSV54584142, COSV99524994; called by muse, mutect2, varscan2
- ACTR8 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 253/578 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51637940; called by muse, mutect2, varscan2
- ADAM23 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52209510; called by muse, varscan2
- ADAM28 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 158/397 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs377655974; called by muse, mutect2, varscan2
- ADAMTS10 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 270/630 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.957); catalogued as COSV54358810; called by muse, mutect2
- ADAMTS13 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 122/565 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1554792426; called by muse, mutect2, varscan2
- ADAMTS8 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 179/793 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1452998761; called by muse, mutect2, varscan2
- ADAMTS9 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55779408; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 132/579 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318980556; called by muse, mutect2, varscan2
- ADCK2 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 101/645 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50783062, COSV50784008; called by muse, mutect2, varscan2
- ADCY9 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 105/467 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1399804998, COSV53579925; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 273/654 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs374708368; called by muse, mutect2, varscan2
- ADGB | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58856191; called by muse, mutect2, varscan2
- ADGRB1 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1480959221; called by muse, mutect2
- ADGRE1 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.769); catalogued as rs147493424; called by muse, mutect2, varscan2
- ADGRE3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs1166647173, COSV53730748; called by muse, mutect2, varscan2
- ADGRF4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 219/504 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51949913; called by muse, mutect2, varscan2
- ADGRF5 | c.3667G>A p.V1223I | Missense Mutation (SNP) | VAF 275/590 reads (47%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.52); catalogued as rs1225532020; called by muse, mutect2, varscan2
- ADGRG4 | c.5599G>A p.G1867R | Missense Mutation (SNP) | VAF 172/322 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54966625; called by muse, mutect2, varscan2
- ADGRG4 | c.8936G>A p.G2979E | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54963928; called by muse, mutect2
- ADGRV1 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 159/602 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); catalogued as CM0911267, COSV67987929; called by muse, mutect2, varscan2
- ADRA1D | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 54/1843 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65241850; called by muse, mutect2
- ADRB2 | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 141/600 reads (24%) | catalogued as COSV60006190; called by muse, varscan2
- AGBL5 | c.2552G>A p.S851N | Missense Mutation (SNP) | VAF 131/607 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as rs755038675; called by muse, mutect2, varscan2
- AGGF1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100462344; called by muse, mutect2, varscan2
- AGMAT | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 505/1060 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1188948300; called by muse, mutect2
- AGO1 | c.1398G>A p.K466= | Splice Region (SNP) | VAF 52/270 reads (19%) | catalogued as COSV64596558; called by muse, mutect2, varscan2
- AGRN | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 346/754 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs764702249; called by muse, mutect2
- AGRN | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 172/634 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101038779; called by muse, mutect2, varscan2
- AHCYL2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 185/1170 reads (16%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs779001507; called by muse, mutect2, varscan2
- AIP | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs536239840; called by muse, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 119/533 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, varscan2
- AIRE | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 112/646 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV99381454; called by muse, mutect2, varscan2
- AKAP12 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 138/636 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs903900798; called by muse, varscan2
- AKAP13 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 120/576 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs752179320; called by muse, mutect2, varscan2
- AKAP13 | c.6547G>A p.D2183N (on ENST00000394518 / NM_007200.5; = p.D2187N on NM_006738.6) | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs776441394; called by muse, mutect2, varscan2
- AKIP1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1413331170; called by muse, mutect2, varscan2
- AKNA | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 140/506 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs770746845; called by muse, mutect2, varscan2
- AL035460.1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 204/1450 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as rs1275163964; called by muse, mutect2, varscan2
- AL121899.2 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 127/1116 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101198469, COSV67351237; called by muse, mutect2, varscan2
- ALG3 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 246/1052 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1479002923; called by muse, mutect2, varscan2
- ALKBH3 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV57023412; called by muse, mutect2, varscan2
- ALMS1 | c.3238C>A p.P1080T | Missense Mutation (SNP) | VAF 105/683 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as COSV52522582; called by muse, mutect2, varscan2
- ALOX15 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 144/700 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541442; called by muse, mutect2, varscan2
- ALX4 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 29/729 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1287276795; called by muse, mutect2
- AMER3 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 148/817 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs551366921, COSV58469216, COSV58470670; called by muse, mutect2, varscan2
- AMHR2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs771778307; called by muse, mutect2, varscan2
- ANGPT4 | c.309G>A p.K103= | Splice Region (SNP) | VAF 73/515 reads (14%) | catalogued as rs1453399419; called by muse, mutect2, varscan2
- ANK3 | c.10696C>T p.P3566S | Missense Mutation (SNP) | VAF 282/594 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.335); catalogued as rs768050877; called by muse, mutect2, varscan2
- ANKIB1 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 97/691 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs964520279; called by muse, mutect2, varscan2
- ANKLE1 | c.1948C>T p.L650F (on ENST00000394458; = p.L596F on NM_152363.6) | Missense Mutation (SNP) | VAF 339/767 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs779030725, COSV101082168; called by muse, mutect2, varscan2
- ANKMY1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 247/496 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1423953853; called by muse, mutect2, varscan2
- ANKRD11 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 153/651 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV56364072; called by muse, mutect2, varscan2
- ANKRD37 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 240/478 reads (50%) | catalogued as rs768367964; called by muse, mutect2, varscan2
- ANKRD54 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 120/459 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as rs1232758185; called by muse, mutect2, varscan2
- ANKS4B | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61139661; called by muse, mutect2, varscan2
- ANKUB1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 173/347 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV67168124, COSV67168205; called by muse, mutect2, varscan2
- ANKZF1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 116/692 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs376160430; called by muse, mutect2, varscan2
- ANO4 | c.1980G>A p.W660* (on ENST00000392977 / NM_001286615.2; = p.W625* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 82/366 reads (22%) | catalogued as COSV54591510; called by muse, mutect2, varscan2
- AP3M1 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs747979202; called by muse, mutect2, varscan2
- AP4M1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 117/695 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1447839854; called by muse, mutect2, varscan2
- AP5Z1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 248/879 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1056631913; called by muse, mutect2, varscan2
- APBB1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 156/806 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs200152007, COSV54981720; called by muse, mutect2, varscan2
- APOB | c.12025G>A p.V4009M | Missense Mutation (SNP) | VAF 237/609 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs140424976; called by muse, mutect2, varscan2
- APP | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 174/798 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1180882911; called by muse, mutect2, varscan2
- ARFGEF3 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 73/388 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs192623819; called by muse, mutect2, varscan2
- ARHGEF10 | c.556G>A p.E186K (on ENST00000398564; = p.X161_splice on NM_014629.4) | Missense Mutation (SNP) | VAF 106/531 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.026); catalogued as COSV100033432; called by muse, mutect2, varscan2
- ARHGEF18 | c.1635C>T p.S545= (on ENST00000359920 / NM_001130955.2; = p.S441= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 105/388 reads (27%) | catalogued as rs1404434466; called by muse, mutect2, varscan2
- ARHGEF25 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 246/506 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1434570805; called by muse, mutect2
- ARHGEF9 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492046; called by muse, mutect2, varscan2
- ARID2 | c.4820C>T p.P1607L | Missense Mutation (SNP) | VAF 118/540 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1166853627; called by muse, mutect2, varscan2
- ARID4B | c.1909C>T p.H637Y | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs780677392; called by muse, mutect2
- ARL10 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 124/823 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs1180999222; called by muse, mutect2, varscan2
- ARL4D | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 102/543 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1225008880; called by muse, mutect2, varscan2
- ARMC8 | c.1106G>A p.G369E (on ENST00000469044 / NM_001363941.2; = p.G355E on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV61768716; called by muse, mutect2, varscan2
- ARMH4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50777905; called by muse, mutect2, varscan2
- ARSH | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1252317392; called by muse, mutect2, varscan2
- ARSJ | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 115/488 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs756095959; called by muse, mutect2, varscan2
- ASAH1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190139418; called by muse, mutect2, varscan2
- ASB11 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768472092; called by muse, mutect2, varscan2
- ASCL5 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 351/690 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs923401269; called by muse, mutect2, varscan2
- ASH1L | c.4243C>T p.P1415S | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV100853120; called by muse, mutect2, varscan2
- ASPSCR1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 31/1014 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs903138359, COSV60731446; called by muse, mutect2
- ASXL1 | c.4495G>A p.V1499M | Missense Mutation (SNP) | VAF 383/1126 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.577); catalogued as rs761827265; called by muse, mutect2, varscan2
- ATAD2 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 99/452 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1347687620; called by muse, mutect2, varscan2
- ATAD2B | c.3338G>A p.R1113Q | Missense Mutation (SNP) | VAF 95/463 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs1172052793; called by muse, mutect2, varscan2
- ATE1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 89/565 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs765527392; called by muse, mutect2, varscan2
- ATF6B | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 94/585 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100913563; called by muse, mutect2, varscan2
- ATG4D | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 141/639 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs756130278; called by muse, mutect2, varscan2
- ATG7 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs981411540; called by muse, mutect2, varscan2
- ATN1 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 113/598 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs781849378; called by muse, mutect2, varscan2
- ATP2B2 | c.2570G>A p.G857D (on ENST00000352432; = p.G823D on NM_001683.5) | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100659921; called by muse, mutect2
- ATP6V1B2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV52353183; called by muse, mutect2
- ATP8A2 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761451341; called by muse, mutect2, varscan2
- ATP8A2 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 127/496 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1435163235; called by muse, mutect2, varscan2
- ATXN2L | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 77/496 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1247950681; called by muse, mutect2, varscan2
- ATXN2L | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1269710768; called by muse, mutect2, varscan2
- ATXN7L2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 148/730 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs888292017; called by muse, mutect2, varscan2
- AUTS2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 171/1656 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.077); catalogued as rs768911898; called by muse, mutect2, varscan2
- AUTS2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 357/1179 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs1222966716; called by muse, mutect2, varscan2
- AUTS2 | c.2779C>T p.R927C | Missense Mutation (SNP) | VAF 156/1403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs758313517; called by muse, mutect2, varscan2
- B3GALNT1 | c.959G>A p.W320* | Nonsense Mutation (SNP) | VAF 66/441 reads (15%) | catalogued as rs1458558563, CM024382; called by muse, mutect2, varscan2
- B3GALT1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 132/687 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59908583; called by muse, mutect2, varscan2
- B4GALNT3 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 98/612 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1015447030; called by muse, mutect2, varscan2
- BAG5 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 109/530 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs772997426; called by muse, mutect2, varscan2
- BAIAP2L2 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 188/786 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs780264497; called by muse, mutect2, varscan2
- BANK1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs755011696; called by muse, mutect2, varscan2
- BAZ2A | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 72/405 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); catalogued as rs746970308; called by muse, mutect2, varscan2
- BBS2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs376483931; called by muse, mutect2, varscan2
- BBS9 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs763548323; called by muse, mutect2, varscan2
- BCAN | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 158/922 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463547932; called by muse, mutect2, varscan2
- BCAN | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 156/642 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1263833249; called by muse, varscan2
- BCAN | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 173/712 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1284107409; called by muse, mutect2, varscan2
- BCAT1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 191/427 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678889; called by muse, mutect2, varscan2
- BCKDHB | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 47/288 reads (16%) | catalogued as rs371117671, CM076020; called by muse, mutect2, varscan2
- BCL2L12 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 140/529 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.58); catalogued as rs138111341; called by muse, mutect2, varscan2
- BCL9L | c.4340G>A p.S1447N | Missense Mutation (SNP) | VAF 173/1066 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52685493, COSV52686582; called by muse, mutect2, varscan2
- BCOR | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 27/603 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as COSV60719321; called by muse, mutect2
- BCR | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 245/993 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1379784513; called by muse, mutect2, varscan2
- BFSP2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 160/853 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100183954; called by muse, mutect2, varscan2
- BFSP2 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 132/649 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56590821; called by muse, mutect2, varscan2
- BICD1 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 235/555 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); catalogued as COSV55688153; called by muse, mutect2, varscan2
- BIRC3 | c.1622-1G>A p.X541_splice | Splice Site (SNP) | VAF 91/314 reads (29%) | catalogued as COSV54817668; called by muse, mutect2, varscan2
- BIRC7 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 141/1237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53903332; called by muse, varscan2
- BLK | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 236/536 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs768937409; called by muse, mutect2, varscan2
- BLMH | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 102/423 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as rs1173537308; called by muse, mutect2, varscan2
- BMP2K | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 159/376 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs1484364480; called by muse, mutect2, varscan2
- BMPR2 | c.3067G>A p.G1023S | Missense Mutation (SNP) | VAF 116/544 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1049284289; called by muse, mutect2, varscan2
- BPI | c.772G>A p.E258K (on ENST00000262865; = p.E254K on NM_001725.3) | Missense Mutation (SNP) | VAF 140/468 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53407454; called by muse, mutect2, varscan2
- BPTF | c.8869G>A p.D2957N | Missense Mutation (SNP) | VAF 35/377 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99068335; called by muse, mutect2
- BRAP | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 100/539 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRCA1 | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 114/594 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1395897649, COSV58790037; called by muse, mutect2, varscan2
- BRCA1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 239/546 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV58789003; called by muse, mutect2, varscan2
- BRCA2 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as CM099631; called by muse, mutect2, varscan2
- BRCA2 | c.5515G>A p.V1839I | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs776630512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 172/412 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1439180366; called by muse, varscan2
- BRDT | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 101/592 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62863577; called by muse, mutect2, varscan2
- BRF1 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 33/873 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs989494665, COSV59266003; called by muse, mutect2
- BRPF1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 177/727 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57408629; called by muse, mutect2, varscan2
- BST1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1252997098; called by mutect2, varscan2
- BTBD10 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs113696304; called by muse, mutect2, varscan2
- BTBD6 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 140/692 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs767275800; called by muse, mutect2, varscan2
- BTNL8 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 128/569 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1448886776, COSV99180550; called by muse, mutect2, varscan2
- C10orf71 | c.3494G>A p.R1165K | Missense Mutation (SNP) | VAF 353/734 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV60510873; called by muse, mutect2, varscan2
- C11orf97 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 182/613 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.971); catalogued as rs1405555081; called by muse, mutect2, varscan2
- C12orf40 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61131215; called by muse, mutect2, varscan2
- C16orf91 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 143/945 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as rs1440783712; called by muse, mutect2, varscan2
- C16orf96 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 373/825 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1052772599; called by muse, mutect2, varscan2
- C1orf87 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 139/584 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1194387370; called by muse, mutect2, varscan2
- C2CD2L | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 213/478 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs768428400; called by muse, mutect2, varscan2
- C3orf56 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as rs755960469; called by muse, mutect2, varscan2
- C4orf54 | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 85/468 reads (18%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.972); catalogued as rs1178963657; called by muse, mutect2, varscan2
- C6orf15 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 48/833 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV52538763; called by muse, mutect2
- C8B | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 98/516 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1247130412; called by muse, mutect2, varscan2
- C9 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 150/612 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs182243824, COSV54677642; called by muse, mutect2, varscan2
- C9orf57 | c.377G>A p.C126Y (on ENST00000377024 / NM_001371610.1; = p.C104Y on NM_001128618.2) | Missense Mutation (SNP) | VAF 182/410 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65462920; called by muse, mutect2, varscan2
- CABIN1 | c.6017C>T p.P2006L | Missense Mutation (SNP) | VAF 107/589 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs200720834, COSV54080796; called by muse, mutect2, varscan2
- CABP4 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 178/860 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56886078; called by muse, mutect2, varscan2
- CACHD1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51558903; called by muse, mutect2, varscan2
- CACNA1S | c.4933G>A p.E1645K | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as rs956710240; called by muse, mutect2, varscan2
- CACNA2D4 | c.3309G>A p.E1103= | Splice Region (SNP) | VAF 255/895 reads (28%) | catalogued as rs1253613757, COSV99765652; called by muse, mutect2, varscan2
- CALHM1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 365/789 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs754905270; called by muse, mutect2, varscan2
- CALML4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 159/578 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776462687, COSV61205841; called by muse, varscan2
- CAMK4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 246/500 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV56679945; called by muse, mutect2, varscan2
- CAMSAP2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1287929408; called by muse, mutect2, varscan2
- CAMSAP2 | c.718C>T p.P240S (on ENST00000236925 / NM_001297707.2; = p.P229S on NM_203459.3) | Missense Mutation (SNP) | VAF 113/503 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52671459; called by muse, mutect2, varscan2
- CAMSAP2 | c.2656G>A p.G886R (on ENST00000236925 / NM_001297707.2; = p.G875R on NM_203459.3) | Missense Mutation (SNP) | VAF 210/483 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV52666633; called by muse, mutect2, varscan2
- CAPN14 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 90/729 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs1055630062; called by muse, mutect2, varscan2
- CAPRIN2 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 85/538 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs747738361, COSV51831536; called by muse, mutect2, varscan2
- CARMIL2 | c.4217C>T p.P1406L | Missense Mutation (SNP) | VAF 107/798 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1241134987; called by muse, varscan2
- CARNMT1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 216/898 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1490236133; called by muse, varscan2
- CASK | c.2515C>T p.P839S (on ENST00000378163 / NM_001367721.1; = p.P834S on NM_003688.3) | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778081066; called by muse, mutect2, varscan2
- CASKIN1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 333/1253 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs778233282; called by muse, mutect2, varscan2
- CASP4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67744951; called by muse, mutect2
- CASP4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1439830902; called by muse, mutect2, varscan2
- CAT | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99573044; called by muse, mutect2, varscan2
- CATSPERB | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs1482335740; called by muse, mutect2, varscan2
- CATSPERB | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 179/432 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764572295; called by muse, mutect2, varscan2
- CATSPERG | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 145/681 reads (21%) | catalogued as rs1300526229; called by muse, mutect2, varscan2
- CATSPERG | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 156/612 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99287077; called by muse, varscan2
- CBFA2T3 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 177/1078 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs138972836; called by muse, mutect2, varscan2
- CBLC | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 164/715 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751768100; called by muse, mutect2, varscan2
- CC2D1A | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 120/597 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV58784426; called by muse, mutect2, varscan2
- CCDC142 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 34/954 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1166866076; called by muse, mutect2
- CCDC157 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 31/867 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1004947996; called by muse, mutect2
- CCDC168 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 85/387 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as rs1269414111; called by muse, mutect2, varscan2
- CCDC180 | c.4813G>A p.A1605T | Missense Mutation (SNP) | VAF 234/240 reads (98%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV63834163; called by muse, varscan2
- CCDC181 | c.1318G>A p.E440K (on ENST00000367806 / NM_001300969.1; = p.E439K on NM_021179.2) | Missense Mutation (SNP) | VAF 102/527 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61393937; called by muse, mutect2, varscan2
- CCDC194 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 203/1134 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1157091753; called by muse, mutect2, varscan2
- CCDC78 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 142/594 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1440693595; called by muse, varscan2
- CCDC82 | c.1566+1G>A p.X522_splice | Splice Site (SNP) | VAF 52/250 reads (21%) | catalogued as COSV53593975; called by muse, mutect2, varscan2
- CCHCR1 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 302/1109 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs140284482; called by muse, mutect2, varscan2
- CD163 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 97/550 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV100775572; called by muse, mutect2, varscan2
- CD163L1 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 205/475 reads (43%) | catalogued as rs1270140389; called by muse, mutect2, varscan2
- CD2AP | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 74/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100830579; called by muse, varscan2
- CD47 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1451808171; called by muse, mutect2, varscan2
- CDAN1 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs772220967; called by muse, varscan2
- CDC16 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 92/396 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV52960835; called by muse, mutect2, varscan2
- CDC25A | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1289950255; called by muse, mutect2, varscan2
- CDC42BPA | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62009056; called by muse, mutect2, varscan2
- CDCA3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1456523153, COSV99976936; called by muse, mutect2, varscan2
- CDCA5 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV51869294; called by muse, mutect2
- CDCP2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 147/515 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs1224911236; called by muse, mutect2, varscan2
- CDH11 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 199/453 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); catalogued as COSV51762172; called by muse, mutect2, varscan2
- CDHR3 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 110/801 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs745585981; called by muse, mutect2, varscan2
- CDK10 | c.955G>A p.E319K (on ENST00000353379 / NM_052988.5; = p.E248K on NM_052987.4) | Missense Mutation (SNP) | VAF 257/553 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs760259251; called by muse, mutect2, varscan2
- CDK12 | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 63/415 reads (15%) | catalogued as COSV101420398, COSV70999045; called by muse, mutect2, varscan2
- CDK3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs775227568; called by muse, mutect2, varscan2
- CDK6 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 179/641 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV56005665; called by muse, mutect2, varscan2
- CDKL5 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM139220; called by muse, mutect2, varscan2
- CDON | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs372823373; called by muse, mutect2, varscan2
- CEACAM3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 132/535 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1555827515; called by muse, mutect2, varscan2
- CELSR1 | c.8357G>A p.G2786E | Missense Mutation (SNP) | VAF 136/668 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs1345420572; called by muse, varscan2
- CENPF | c.7897G>A p.A2633T | Missense Mutation (SNP) | VAF 302/636 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100871634; called by muse, mutect2, varscan2
- CEP170B | c.1321C>T p.P441S (on ENST00000453495; = p.P370S on NM_015005.3) | Missense Mutation (SNP) | VAF 60/1256 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV69023753; called by muse, mutect2
- CEP250 | c.4202G>A p.R1401K | Missense Mutation (SNP) | VAF 323/1067 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV100698664; called by muse, mutect2, varscan2
- CEP250 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 123/866 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1480576003; called by muse, mutect2, varscan2
- CEP350 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs762781537; called by muse, mutect2, varscan2
- CERS2 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 142/602 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1036369299; called by muse, mutect2
- CERT1 | c.2182C>G p.R728G (on ENST00000405807 / NM_001130105.1; = p.R600G on NM_005713.3) | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655779; called by muse, mutect2, varscan2
- CFAP65 | c.344C>T p.T115I (on ENST00000341552 / NM_194302.4; = p.T50I on NM_152389.4) | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs1337523254; called by muse, mutect2, varscan2
- CFAP94 | c.583G>A p.A195T (on ENST00000320267 / NM_001352064.2; = p.A201T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs1227230173; called by muse, mutect2, varscan2
- CFTR | c.2888C>T p.T963I | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs551092617; called by muse, mutect2, varscan2
- CHD4 | c.2336G>A p.R779Q (on ENST00000357008 / NM_001363606.2; = p.R792Q on NM_001273.5) | Missense Mutation (SNP) | VAF 55/826 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58897494; called by muse, mutect2
- CHD5 | c.5539C>T p.L1847F | Missense Mutation (SNP) | VAF 125/643 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs761495028; called by muse, mutect2, varscan2
- CHD5 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 197/896 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1333162189; called by mutect2, varscan2
- CHD6 | c.6965C>T p.A2322V | Missense Mutation (SNP) | VAF 255/847 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs754820590; called by muse, mutect2, varscan2
- CHD7 | c.3347A>G p.K1116R | Missense Mutation (SNP) | VAF 338/732 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs750214154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.4982G>A p.G1661D (on ENST00000646647 / NM_001170629.2; = p.G1382D on NM_020920.4) | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63219173; called by muse, mutect2, varscan2
- CHL1 | c.2056G>A p.V686I (on ENST00000397491 / NM_001253387.1; = p.V702I on NM_006614.4) | Missense Mutation (SNP) | VAF 214/478 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1305736477; called by muse, mutect2, varscan2
- CHN1 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 54/398 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1294929523; called by muse, mutect2, varscan2
- CHPF2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 182/1104 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV50390364; called by muse, varscan2
- CHRM2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 136/475 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57777228; called by muse, mutect2, varscan2
- CHRNA4 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 195/1256 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs1435870435; called by muse, mutect2, varscan2
- CHRNB4 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 27/638 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1273095175; called by muse, mutect2
- CHST7 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 239/557 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1160163340; called by muse, mutect2, varscan2
- CIC | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 134/1005 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs1438541724; called by muse, varscan2
- CIC | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 298/1141 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1568486138; called by muse, mutect2, varscan2
- CIC | c.4045G>A p.V1349I | Missense Mutation (SNP) | VAF 288/554 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV50640263; called by muse, mutect2, varscan2
- CILP2 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 172/852 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752372369, COSV52275672; called by muse, mutect2, varscan2
- CIT | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV55881496; called by muse, mutect2, varscan2
- CLASP1 | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 242/506 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1337033275; called by muse, mutect2, varscan2
- CLASP1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs370412928; called by muse, mutect2, varscan2
- CLEC4M | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99940374; called by muse, mutect2, varscan2
- CLMN | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs1238577004; called by muse, mutect2, varscan2
- CLPB | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1304746089; called by muse, mutect2, varscan2
- CLSTN2 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 136/845 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs900952461, COSV71724080; called by mutect2, varscan2
- CLTCL1 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 133/626 reads (21%) | catalogued as rs371582873; called by muse, mutect2, varscan2
- CNGB1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 108/446 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.267); catalogued as rs1213983177, COSV51904227; called by muse, mutect2, varscan2
- CNPY2 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 122/566 reads (22%) | catalogued as COSV99228376; called by muse, mutect2, varscan2
- CNTN4 | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs770392035, COSV61868002; called by muse, mutect2, varscan2
- CNTNAP1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 145/642 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.835); catalogued as rs1257297280; called by muse, mutect2, varscan2
- CNTNAP4 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.309); catalogued as rs113615192; called by muse, mutect2, varscan2
- COASY | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 148/588 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs775808304; called by muse, mutect2, varscan2
- COASY | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 119/618 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367406740; called by muse, mutect2, varscan2
- COIL | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 88/464 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53596328; called by muse, varscan2
- COL11A1 | c.3134G>A p.G1045E | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616959; called by muse, mutect2, varscan2
- COL13A1 | c.917G>A p.G306E (on ENST00000398978 / NM_001130103.2; = p.G249E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/427 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62570131; called by muse, mutect2, varscan2
- COL16A1 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 150/758 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs547294000; called by muse, mutect2, varscan2
- COL24A1 | c.2681G>A p.G894D | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774123402, COSV65314127; called by muse, mutect2, varscan2
- COL27A1 | c.4786G>A p.D1596N | Missense Mutation (SNP) | VAF 79/516 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV61922547; called by muse, mutect2, varscan2
- COL28A1 | c.124+1G>A p.X42_splice | Splice Site (SNP) | VAF 135/420 reads (32%) | catalogued as rs1177880580; called by muse, mutect2, varscan2
- COL4A1 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 311/674 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148781420; called by muse, mutect2, varscan2
- COL4A5 | c.3553G>A p.G1185S | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1353480777; called by muse, mutect2, varscan2
- COL4A5 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs757653472, CM1310548; called by muse, mutect2
- COL6A5 | c.7478G>A p.R2493H (on ENST00000312481; = p.R2489H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs760416331; called by muse, mutect2, varscan2
- COL8A2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 102/772 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1259476914; called by muse, varscan2
- COMMD3-BMI1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs376503129; called by muse, mutect2, varscan2
- COMMD6 | c.54+1G>A p.X18_splice | Splice Site (SNP) | VAF 109/798 reads (14%) | catalogued as rs1224511735, COSV63322728; called by muse, mutect2, varscan2
- COPB2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 75/422 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs546968520; called by muse, mutect2, varscan2
- CORO6 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61470699, COSV61470999; called by muse, mutect2, varscan2
- CPA1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 120/838 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1554411232, CM139212, COSV99163261; called by muse, mutect2, varscan2
- CPNE7 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 169/652 reads (26%) | catalogued as COSV52015633; called by muse, mutect2, varscan2
- CRB1 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV100957607, COSV66332650; called by muse, mutect2, varscan2
- CREB1 | c.689G>A p.G230E (on ENST00000432329 / NM_134442.5; = p.G216E on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753817619; called by muse, mutect2, varscan2
- CREB3L3 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV50175434; called by muse, mutect2, varscan2
- CREBBP | c.6160C>T p.P2054S | Missense Mutation (SNP) | VAF 490/954 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV52131848; called by muse, varscan2
- CRIP2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 25/623 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555436750; called by muse, mutect2
- CRISP2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 190/434 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs754988764; called by muse, varscan2
- CRPPA | c.1274G>A p.S425N (on ENST00000407010 / NM_001368197.1; = p.S375N on NM_001101417.4) | Missense Mutation (SNP) | VAF 90/511 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1337797656; called by muse, mutect2, varscan2
- CSMD1 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 168/709 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1470298101; called by muse, mutect2, varscan2
- CSMD2 | c.7793G>A p.S2598N | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1311974947; called by muse, mutect2, varscan2
- CSMD3 | c.4472C>T p.P1491L (on ENST00000297405 / NM_001363185.1; = p.P1387L on NM_052900.3) | Missense Mutation (SNP) | VAF 99/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1489502163; called by muse, mutect2, varscan2
- CSNK2A1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 175/617 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs1225143921; called by muse, mutect2, varscan2
- CSPG5 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 451/897 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53133133; called by muse, mutect2, varscan2
- CSPP1 | c.1627C>T p.P543S (on ENST00000676605; = p.P502S on NM_024790.6) | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV51592284; called by muse, mutect2, varscan2
- CSRNP1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 28/822 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949881028; called by muse, mutect2
- CST1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 204/797 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs756782667; called by muse, varscan2
- CTDP1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 260/1074 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs762885419; called by muse, mutect2, varscan2
- CTNS | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 101/442 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110323; called by muse, mutect2, varscan2
- CTSS | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV64566149; called by muse, mutect2, varscan2
- CUX2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99920996; called by muse, mutect2, varscan2
- CWF19L2 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99980250; called by muse, mutect2, varscan2
- CYP17A1 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 60/417 reads (14%) | catalogued as CD064541; called by muse, mutect2, varscan2
- CYP1A1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 87/634 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1019779925; called by muse, mutect2, varscan2
- CYP1B1 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 106/600 reads (18%) | catalogued as CM148173; called by muse, mutect2, varscan2
- CYP26B1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 330/697 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV50012203; called by muse, varscan2
- CYP2B6 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 109/496 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs945106154; called by muse, mutect2, varscan2
- CYP2D6 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 100/919 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1244836219; called by muse, mutect2, varscan2
- CYP2D6 | c.666G>A p.E222= | Splice Region (SNP) | VAF 115/681 reads (17%) | catalogued as COSV62245231; called by muse, mutect2, varscan2
- CYP2S1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 386/861 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as rs976154000; called by muse, mutect2, varscan2
- CYP2W1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 449/1434 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs141228662; called by muse, mutect2, varscan2
- CYP3A7 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.066); catalogued as rs1181850389; called by muse, mutect2
- CYP4A22 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 372/759 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53738432; called by muse, mutect2, varscan2
- CYP4F12 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs556006739; called by muse, mutect2, varscan2
- DAAM1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 211/484 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62839720; called by muse, mutect2, varscan2
- DBF4B | c.19G>T p.G7* | Nonsense Mutation (SNP) | VAF 26/636 reads (4%) | catalogued as rs1274347150; called by muse, mutect2
- DBN1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 154/816 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV52794174; called by mutect2, varscan2
- DCAF1 | c.3755T>C p.I1252T | Missense Mutation (SNP) | VAF 257/536 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV60047030; called by muse, mutect2, varscan2
- DCAF12L1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 197/387 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV64422471; called by muse, mutect2, varscan2
- DCAF16 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 241/554 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1454777841; called by muse, mutect2, varscan2
- DCLK2 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.101); catalogued as rs749078554; called by muse, mutect2, varscan2
- DCTN3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 116/977 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1481861771; called by muse, mutect2, varscan2
- DDR1 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 191/777 reads (25%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.995); catalogued as rs765835603; called by muse, mutect2, varscan2
- DDX27 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 30/884 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404464320, COSV65611107; called by muse, mutect2
- DDX54 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 244/981 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1055555413; called by muse, mutect2, varscan2
- DENND1A | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 376/813 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as COSV65349538; called by muse, mutect2, varscan2
- DENND3 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 198/800 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs754247305; called by muse, varscan2
- DENND4B | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 126/464 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100768333, COSV63410780; called by muse, mutect2, varscan2
- DGKE | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 152/367 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1235326725; called by muse, mutect2, varscan2
- DGKI | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 242/1152 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs975497755; called by muse, varscan2
- DHRS9 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 122/540 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59141774; called by muse, mutect2, varscan2
- DHX57 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 31/644 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1004526810; called by muse, mutect2
- DHX8 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 66/393 reads (17%) | catalogued as COSV99292418; called by muse, mutect2, varscan2
- DHX8 | c.2999G>A p.G1000D | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV52257001; called by muse, mutect2, varscan2
- DIDO1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 168/1277 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs751584757, COSV56632753; called by muse, mutect2, varscan2
- DISP3 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 104/561 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV53841249; called by muse, mutect2, varscan2
- DIXDC1 | c.1207C>T p.H403Y (on ENST00000440460 / NM_001037954.4; = p.H192Y on NM_033425.4) | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as rs1555174662; called by muse, mutect2, varscan2
- DKK1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1339223000; called by muse, mutect2
- DLGAP3 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 205/954 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as rs868214933; called by muse, mutect2, varscan2
- DLL1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 151/634 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1185776829; called by muse, mutect2, varscan2
- DLST | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs145271238; called by muse, mutect2, varscan2
- DMKN | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 81/498 reads (16%) | catalogued as COSV100304004; called by muse, mutect2, varscan2
- DMPK | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 216/812 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV52182925; called by muse, mutect2, varscan2
- DMRTC2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 143/888 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54187436; called by muse, mutect2, varscan2
- DNAAF2 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 145/838 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1298518158; called by muse, mutect2, varscan2
- DNAH1 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 276/568 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs762346571; called by muse, mutect2, varscan2
- DNAH17 | c.8987C>T p.T2996I | Missense Mutation (SNP) | VAF 108/459 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs760989551; called by muse, mutect2, varscan2
- DNAH6 | c.8431G>A p.V2811I | Missense Mutation (SNP) | VAF 179/415 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs375086278; called by muse, mutect2, varscan2
- DNAH7 | c.6971G>A p.S2324N | Missense Mutation (SNP) | VAF 120/557 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs992819121; called by muse, mutect2, varscan2
- DNAH9 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 399/865 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1175364860; called by muse, mutect2, varscan2
- DNAH9 | c.11567C>T p.A3856V | Missense Mutation (SNP) | VAF 90/472 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as CM124438; called by muse, mutect2, varscan2
- DNAI1 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 60/880 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99647203; called by muse, mutect2
- DNAJB1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 93/498 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54317811; called by muse, varscan2
- DNAJB6 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 61/510 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs778861039; called by muse, mutect2, varscan2
- DNHD1 | c.13984G>A p.E4662K | Missense Mutation (SNP) | VAF 111/735 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs1465169501; called by muse, mutect2, varscan2
- DNMT3A | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 144/610 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs34191084; called by muse, mutect2, varscan2
- DOCK4 | c.5494C>T p.H1832Y | Missense Mutation (SNP) | VAF 152/949 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs374966318; called by muse, mutect2, varscan2
- DOCK5 | c.4448G>A p.W1483* | Nonsense Mutation (SNP) | VAF 69/354 reads (19%) | catalogued as rs1385775300, COSV52401014; called by muse, mutect2, varscan2
- DOCK9 | c.3834C>T p.H1278= (on ENST00000376460 / NM_001366676.2; = p.H1279= on NM_015296.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 85/386 reads (22%) | catalogued as rs1451592639; called by muse, mutect2, varscan2
- DOK5 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 84/793 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99374199; called by muse, mutect2, varscan2
- DPH2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 52/1112 reads (5%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.542); catalogued as rs1473837474; called by muse, mutect2
- DRAP1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 158/589 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs753718615; called by muse, mutect2, varscan2
- DROSHA | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as rs1464818570; called by muse, mutect2
- DSG3 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 151/587 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV57125160; called by muse, mutect2, varscan2
- DSP | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 298/686 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs374283517; called by muse, mutect2, varscan2
- DST | c.16246G>A p.A5416T (on ENST00000361203 / NM_001374722.1; = p.A3004T on NM_015548.5) | Missense Mutation (SNP) | VAF 91/597 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV55021306; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 68/645 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50051473; called by muse, mutect2
- DUSP5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 327/1340 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.515); catalogued as rs774167871; called by muse, mutect2, varscan2
- DUSP5 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 158/638 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV63645505; called by muse, mutect2, varscan2
- DYRK1A | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 253/504 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs753226962; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYSF | c.5584G>A p.G1862R | Missense Mutation (SNP) | VAF 135/596 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1393147629; called by muse, mutect2, varscan2
- E2F5 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99809885; called by muse, mutect2, varscan2
- E4F1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 134/583 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199803798; called by muse, mutect2, varscan2
- ECPAS | c.4145C>T p.T1382I | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs758346554; called by muse, mutect2, varscan2
- ECPAS | c.3767G>A p.G1256E | Missense Mutation (SNP) | VAF 136/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309372797; called by muse, mutect2, varscan2
- ECT2 | c.2242G>A p.E748K (on ENST00000392692 / NM_001349098.2; = p.E717K on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1336811997; called by muse, mutect2, varscan2
- EDAR | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 126/561 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471093049; called by muse, mutect2, varscan2
- EDC4 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 80/574 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as rs1240298344; called by muse, mutect2, varscan2
- EDNRB | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 133/601 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs200579208; called by muse, mutect2, varscan2
- EFNB3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 95/404 reads (24%) | catalogued as COSV99872709; called by muse, mutect2, varscan2
- EGFR | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 349/2146 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV51804378; called by muse, mutect2, varscan2
- EGFR | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 229/2480 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764780987; called by muse, mutect2
- EGR4 | c.764C>T p.A255V (on ENST00000545030; = p.A152V on NM_001965.4) | Missense Mutation (SNP) | VAF 216/899 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1284243020; called by muse, mutect2, varscan2
- EIF2AK1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs774736402, COSV52236537; called by muse, mutect2, varscan2
- EIF2B3 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 118/437 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1456181265; called by muse, mutect2, varscan2
- EIF4E3 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs779891581; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 344/658 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs761982631, COSV57517257; called by muse, varscan2
- ELAC2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 174/735 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1398310385, COSV100568351; called by muse, mutect2, varscan2
- ELAVL1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60965993; called by muse, mutect2, varscan2
- EMB | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 182/735 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); catalogued as rs750541683; called by muse, mutect2, varscan2
- EMID1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 73/530 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs267606215, COSV100469199; called by muse, mutect2, varscan2
- EML6 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1258855038; called by muse, mutect2, varscan2
- EMSY | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 123/620 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.13); catalogued as rs764009276, COSV58260545; called by muse, mutect2, varscan2
- ENAM | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as rs368423807; called by muse, mutect2, varscan2
- ENDOU | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 48/469 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs749188968; called by muse, mutect2, varscan2
- ENPP1 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs200239821, COSV62935669; called by muse, varscan2
- ENPP7 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 42/808 reads (5%) | catalogued as COSV60386163; called by muse, mutect2
- ENTPD1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 294/671 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1195301450; called by muse, mutect2, varscan2
- ENTPD4 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 135/497 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100652764, COSV100652820; called by muse, mutect2, varscan2
- ENTPD6 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 127/794 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs200552433; called by muse, mutect2, varscan2
- EP300 | c.5669C>T p.T1890I | Missense Mutation (SNP) | VAF 224/1163 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs146165770; called by muse, mutect2, varscan2
- EP400 | c.8455C>T p.P2819S | Missense Mutation (SNP) | VAF 198/942 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.059); catalogued as rs1238202759; called by muse, mutect2, varscan2
- EPB41L1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 121/938 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99150106; called by muse, mutect2, varscan2
- EPB42 | c.10+6C>T | Splice Region (SNP) | VAF 131/510 reads (26%) | catalogued as rs200354161; called by muse, mutect2, varscan2
- EPHA10 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 226/484 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs775096565; called by muse, mutect2, varscan2
- EPHA4 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 103/565 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as rs146488160; called by muse, mutect2, varscan2
- EPHA4 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.975); catalogued as rs762225060; called by muse, mutect2, varscan2
- EPHA7 | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65182391; called by muse, varscan2
- EPHB2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 399/805 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs762351366; called by muse, mutect2, varscan2
- EPHB2 | c.2448G>A p.M816I (on ENST00000400191 / NM_001309193.2; = p.M817I on NM_004442.7) | Missense Mutation (SNP) | VAF 260/579 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs547041098; called by muse, mutect2, varscan2
- EPPK1 | c.4697C>T p.S1566F | Missense Mutation (SNP) | VAF 195/799 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782526891; called by muse, mutect2, varscan2
- EPRS1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 158/371 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293828261; called by muse, mutect2, varscan2
- EPX | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 359/748 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs189235341; called by muse, mutect2, varscan2
- ERMARD | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs367909990; called by muse, mutect2, varscan2
- ERN2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 23/472 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1387587019; called by muse, mutect2
- ERVFRD-1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 280/580 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100977399; called by muse, varscan2
- ESPN | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 197/840 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs756669745; called by muse, mutect2, varscan2
- ESPNL | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 253/1117 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54540360; called by muse, mutect2, varscan2
- ESRP1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 92/427 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100619668; called by muse, mutect2, varscan2
- ESYT3 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 114/839 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs1288317294; called by muse, mutect2, varscan2
- ETFDH | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172356159; called by muse, mutect2, varscan2
- ETV3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 70/728 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs377466641; called by muse, mutect2
- EVPL | c.5645C>T p.A1882V | Missense Mutation (SNP) | VAF 362/731 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757437772; called by muse, mutect2, varscan2
- EXOC3L2 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 131/943 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs200984629; called by muse, mutect2, varscan2
- EXOSC8 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs535085627; called by muse, mutect2, varscan2
- EXPH5 | c.4534C>T p.P1512S | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.596); catalogued as rs775034564; called by muse, mutect2, varscan2
- EXPH5 | c.2171G>A p.G724D | Missense Mutation (SNP) | VAF 246/533 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1383584140; called by muse, mutect2, varscan2
- EXPH5 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 109/515 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as rs766525434, COSV99760735; called by muse, mutect2, varscan2
- EYA3 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV65815576; called by muse, mutect2, varscan2
- F10 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 107/460 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs777432382; called by muse, mutect2, varscan2
- F5 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 116/613 reads (19%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.539); catalogued as COSV63123517; called by muse, mutect2, varscan2
- F8 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64275218; called by muse, mutect2, varscan2
- FAAH | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1180146087; called by muse, varscan2
- FAAP100 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 247/983 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100585603; called by muse, mutect2, varscan2
- FAM131A | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 221/814 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs978267365; called by muse, mutect2, varscan2
- FAM131B | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 353/1072 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761262315; called by muse, mutect2, varscan2
- FAM153CP | n.365-1G>A | Splice Site (SNP) | VAF 114/575 reads (20%) | catalogued as COSV101228637; called by muse, mutect2, varscan2
- FAM160A2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 351/829 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs150676373; called by muse, mutect2, varscan2
- FAM170A | c.984G>A p.R328= | Splice Region (SNP) | VAF 54/380 reads (14%) | catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FAM171A1 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 105/525 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1166569856; called by muse, mutect2, varscan2
- FAM172A | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs746412815, COSV67935420; called by muse, mutect2, varscan2
- FAM186B | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 140/567 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV57720488; called by muse, mutect2, varscan2
- FAM237A | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 129/643 reads (20%) | catalogued as rs1269449706; called by muse, mutect2, varscan2
- FAM53C | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 135/835 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs757244107, COSV99524554; called by muse, mutect2, varscan2
- FAM71A | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 124/624 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54234987; called by muse, mutect2, varscan2
- FAM83F | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 485/1004 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs769914565; called by muse, mutect2, varscan2
- FAM83H | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 135/553 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601817; called by muse, mutect2, varscan2
- FANCF | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 267/1013 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59416514; called by muse, mutect2, varscan2
- FAT2 | c.11786G>A p.G3929D | Missense Mutation (SNP) | VAF 34/876 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as rs1220768722; called by muse, mutect2
- FBLN7 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 69/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs747179865, COSV100485561; called by muse, mutect2, varscan2
- FBN1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 48/857 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555401681, CD098521, COSV57317908; ClinVar: uncertain significance; called by muse, mutect2
- FBN3 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV54469063; called by muse, mutect2, varscan2
- FBRS | c.668C>T p.P223L (on ENST00000287468; = p.P743L on NM_001105079.3) | Missense Mutation (SNP) | VAF 269/1126 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs1277811510; called by muse, mutect2, varscan2
- FBXO10 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 292/295 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1324355073; called by muse, mutect2
- FBXO33 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 236/832 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as rs1404810837; called by muse, mutect2, varscan2
- FBXW5 | c.1245G>A p.R415= | Splice Region (SNP) | VAF 278/649 reads (43%) | catalogued as rs144039568; called by muse, mutect2, varscan2
- FCSK | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 127/691 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs754001619; called by muse, mutect2, varscan2
- FFAR1 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 180/1083 reads (17%) | catalogued as rs374423505; called by muse, mutect2, varscan2
- FFAR3 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 194/1213 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100588226; called by muse, mutect2, varscan2
- FGF22 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 98/581 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376452466; called by muse, mutect2, varscan2
- FGG | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60194939; called by muse, mutect2, varscan2
- FHOD1 | c.2966C>T p.T989I | Missense Mutation (SNP) | VAF 328/720 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777791137; called by muse, mutect2, varscan2
- FHOD1 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 224/467 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422267033; called by muse, varscan2
- FHOD3 | c.1636C>T p.P546S (on ENST00000359247 / NM_001281739.3; = p.P563S on NM_025135.5) | Missense Mutation (SNP) | VAF 99/537 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.057); catalogued as COSV57180793; called by muse, mutect2, varscan2
- FITM1 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 142/619 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.347); catalogued as rs762001311; called by muse, mutect2, varscan2
- FLG | c.11357C>T p.S3786F | Missense Mutation (SNP) | VAF 117/476 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100912513, COSV64252613; called by muse, varscan2
- FLG | c.4454G>A p.G1485D | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV64236092; called by muse, mutect2, varscan2
- FLNA | c.7171C>T p.R2391C (on ENST00000369850 / NM_001110556.2; = p.R2383C on NM_001456.3) | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1480403319, COSV61040462; called by muse, mutect2, varscan2
- FLT4 | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 163/746 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM126124; called by muse, mutect2, varscan2
- FMN2 | c.2788G>A p.G930S | Missense Mutation (SNP) | VAF 156/508 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.209); catalogued as rs748088983; called by muse, mutect2, varscan2
- FN3KRP | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 26/575 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs1174459134; called by muse, mutect2
- FNDC8 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 112/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754997508; called by muse, varscan2
- FOLR3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs765420568; called by muse, mutect2, varscan2
- FOXF1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 190/1052 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs1487470060; called by muse, mutect2, varscan2
- FOXH1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 250/977 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs201165974; called by muse, mutect2, varscan2
- FOXH1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 388/795 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1043646541; called by muse, mutect2, varscan2
- FOXI1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 205/962 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1051087019, COSV60388686; called by muse, mutect2, varscan2
- FRAS1 | c.10663G>A p.E3555K | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53633841, COSV99346846; called by muse, mutect2
- FREM1 | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs1172182793; called by muse, mutect2, varscan2
- FREM3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 232/957 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192229040; called by muse, mutect2, varscan2
- FRMD5 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1280460823; called by muse, mutect2
- FRMD5 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1303234230, COSV68720838; called by muse, mutect2, varscan2
- FUBP1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 65/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53937640; called by muse, mutect2, varscan2
- FUBP1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1434698050; called by muse, mutect2, varscan2
- FUT5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 120/587 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs766383156; called by muse, mutect2, varscan2
- FUT5 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 213/910 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs1408512679; called by muse, mutect2, varscan2
- GAB1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs931202647; called by muse, mutect2, varscan2
- GABBR1 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 124/995 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1253206525; called by muse, mutect2, varscan2
- GABRR2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV68266205; called by muse, mutect2, varscan2
- GAD1 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64025941; called by muse, mutect2, varscan2
- GAK | c.3593C>T p.P1198L | Missense Mutation (SNP) | VAF 178/408 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779077568, COSV58508466; called by muse, mutect2, varscan2
- GALNT6 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 75/585 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV100695600; called by muse, mutect2, varscan2
- GALNTL6 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101487914; called by muse, mutect2, varscan2
- GANC | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 63/370 reads (17%) | PolyPhen benign (0.281); catalogued as COSV58812221; called by muse, mutect2, varscan2
- GATA1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 180/390 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557020321, COSV64962832; called by muse, mutect2, varscan2
- GCKR | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 191/450 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs138402942; called by muse, mutect2, varscan2
- GCNT7 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365878695; called by muse, mutect2, varscan2
- GEMIN5 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 95/516 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs768821490; called by muse, varscan2
- GEN1 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV58057669; called by muse, mutect2, varscan2
- GFY | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 27/898 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394568196; called by muse, mutect2
- GFY | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 228/858 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1233733191; called by muse, mutect2, varscan2
- GGA3 | c.382G>A p.E128K (on ENST00000537686 / NM_138619.4; = p.E95K on NM_014001.5) | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs912675113; called by muse, mutect2, varscan2
- GGN | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 421/840 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1325790631; called by muse, mutect2, varscan2
- GIGYF2 | c.3247G>A p.V1083M | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs557540265; called by muse, mutect2, varscan2
- GIMAP4 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 146/870 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1443456879; called by muse, mutect2, varscan2
- GJC2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 106/524 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1298064694, CD082123; called by muse, mutect2, varscan2
- GMNC | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 93/444 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV71248986; called by muse, mutect2, varscan2
- GNE | c.1960G>A p.G654S (on ENST00000396594 / NM_001128227.3; = p.G623S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/701 reads (14%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV100930087; called by muse, mutect2, varscan2
- GNE | c.1541G>A p.G514E (on ENST00000396594 / NM_001128227.3; = p.G483E on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/752 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64951261; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 342/1661 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1434408883; called by muse, mutect2, varscan2
- GOLGA8M | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 88/457 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.699); catalogued as rs1433657548; called by muse, mutect2, varscan2
- GPAM | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs765572330; called by muse, mutect2, varscan2
- GPATCH8 | c.3908C>T p.A1303V | Missense Mutation (SNP) | VAF 86/559 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs747650422, COSV59193685, COSV59198433; called by muse, mutect2, varscan2
- GPD2 | c.2041C>T p.L681F | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.111); catalogued as COSV60097845; called by muse, mutect2, varscan2
- GPR107 | c.1576C>T p.L526F (on ENST00000372406 / NM_001136557.2; = p.L478F on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/425 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100714688; called by muse, mutect2, varscan2
- GPR137C | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 129/559 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs763627535; called by muse, mutect2, varscan2
- GPR137C | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 153/381 reads (40%) | catalogued as rs867519635, COSV58704821; called by muse, mutect2, varscan2
- GPR180 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs1221402785; called by muse, mutect2, varscan2
- GPR34 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1416165884; called by muse, mutect2, varscan2
- GPRIN2 | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 203/1325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555017506; called by muse, mutect2, varscan2
- GRIK1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as rs963257580; called by muse, mutect2, varscan2
- GRIK4 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 177/398 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs1335757866; called by muse, mutect2, varscan2
- GRIN2C | c.3137_3138insTCCGGAGCC p.E1048_L1049insPPE | In Frame Ins (INS) | VAF 384/776 reads (49%) | catalogued as COSV53109802; called by pindel, varscan2
- GRM1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 136/530 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs1279453638; called by muse, mutect2, varscan2
- GRM4 | c.1895G>A p.G632D | Missense Mutation (SNP) | VAF 156/863 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65211397; called by muse, mutect2, varscan2
- GRWD1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 95/710 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53517666; called by muse, mutect2, varscan2
- GSC | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 162/796 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs752698866; called by muse, mutect2, varscan2
- GSDMC | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.437); catalogued as rs1432815651; called by muse, mutect2
- GSDMC | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149214871; called by muse, mutect2, varscan2
- GSS | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 107/587 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99404438; called by muse, varscan2
- GSS | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 120/823 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.751); catalogued as CM970696; called by muse, varscan2
- GTF2IRD2B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 119/562 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1554532942, COSV57032460; called by muse, mutect2, varscan2
- GTPBP1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 194/827 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99323043; called by muse, mutect2, varscan2
- GUCY1A1 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 94/449 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200927723; called by muse, mutect2, varscan2
- GUCY2D | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 382/874 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as rs1475142231; called by muse, mutect2, varscan2
- GXYLT1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as rs747871804; called by muse, mutect2, varscan2
- GYG1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56048618, COSV56050345; called by muse, mutect2, varscan2
- GYS1 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 188/968 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1177489919; called by muse, mutect2, varscan2
- H2AC12 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 198/445 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1053911294, COSV63617377; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2, varscan2
- H2BC15 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 105/547 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57586190; called by muse, mutect2, varscan2
- H4-16 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 24/694 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV100797598, COSV100797641; called by muse, mutect2
- H4C9 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 44/776 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV62889756; called by muse, mutect2
- HAL | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764135653; called by muse, mutect2, varscan2
- HAO2 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 118/540 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377849; called by muse, mutect2, varscan2
- HAS1 | c.1062G>A p.K354= | Splice Region (SNP) | VAF 468/986 reads (47%) | catalogued as rs552959486; called by muse, mutect2
- HAS1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1226288844, COSV55787415; called by muse, mutect2
- HAS1 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 366/842 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs945398316; called by muse, mutect2, varscan2
- HCN2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 531/1053 reads (50%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.04); catalogued as rs1287052088; called by muse, mutect2, varscan2
- HDAC5 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 205/450 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs560931871; called by muse, mutect2, varscan2
- HDGF | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 139/611 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs750720441; called by muse, mutect2, varscan2
- HDGFL3 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 121/564 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV55206557; called by muse, mutect2, varscan2
- HDHD5 | c.634C>T p.L212F (on ENST00000336737 / NM_033070.3; = p.L182F on NM_017829.5) | Missense Mutation (SNP) | VAF 217/845 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757532322, COSV50088144; called by muse, mutect2, varscan2
- HELZ | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); catalogued as rs1197639514; called by muse, mutect2, varscan2
- HELZ2 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 112/763 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs752210643; called by muse, mutect2, varscan2
- HEMK1 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51750308; called by muse, varscan2
- HEPHL1 | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs891943528; called by muse, mutect2, varscan2
- HEXB | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM126846; called by muse, mutect2, varscan2
- HGF | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 50/676 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV55959735, COSV99735215; called by muse, mutect2
- HHIPL1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 162/836 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58090731; called by muse, varscan2
- HIPK3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 262/521 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100305487; called by muse, mutect2, varscan2
- HIVEP1 | c.3899C>T p.S1300F | Missense Mutation (SNP) | VAF 89/578 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765842096; called by muse, mutect2, varscan2
- HIVEP3 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460785104; called by muse, mutect2
- HIVEP3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 365/744 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs1395382508; called by muse, mutect2, varscan2
- HLTF | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 156/353 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV59500283; called by muse, mutect2, varscan2
- HMG20B | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 255/1023 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as COSV53571930; called by muse, varscan2
- HMOX2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 111/649 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as rs200633966, COSV99566773; called by muse, mutect2, varscan2
- HMX3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 270/1064 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.037); catalogued as COSV63501965; called by mutect2, varscan2
- HNRNPA1 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52935545; called by muse, mutect2, varscan2
- HNRNPM | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 245/566 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249293106, COSV100335292, COSV57691959; called by muse, mutect2, varscan2
- HNRNPM | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 530/1047 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs375484908; called by muse, varscan2
- HOXA11 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 236/956 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50052881; called by muse, mutect2, varscan2
- HOXA7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 220/802 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766593338; called by muse, mutect2, varscan2
- HOXB7 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 237/1113 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs1209031456; called by muse, mutect2, varscan2
- HOXD3 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 150/946 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs1006350962, COSV99980451; called by muse, mutect2, varscan2
- HR | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 112/620 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1198951087; called by muse, mutect2, varscan2
- HRC | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 262/528 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53255644, COSV99417787; called by muse, mutect2, varscan2
- HRNR | c.2759G>A p.G920D | Missense Mutation (SNP) | VAF 205/778 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.099); catalogued as rs755328752; called by muse, mutect2, varscan2
- HSF2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.499); catalogued as rs1418385695; called by muse, mutect2, varscan2
- HSPA12B | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 120/965 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs144262723; called by muse, mutect2, varscan2
- HSPA1L | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 200/653 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); catalogued as rs779447554; called by muse, mutect2, varscan2
- HSPA8 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 28/667 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV57085599; called by muse, mutect2
- HSPBAP1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 189/482 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748268421, COSV60242728; called by muse, mutect2, varscan2
- HSPG2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 235/526 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1388933414; called by muse, mutect2, varscan2
- HTR2A | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 92/677 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66327267; called by muse, mutect2, varscan2
- HYAL2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 351/700 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.285); catalogued as rs782327523; called by muse, mutect2, varscan2
- HYDIN | c.12926C>T p.P4309L | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1455760595; called by muse, mutect2, varscan2
- HYOU1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 57/729 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1414139136, COSV101345599; called by muse, mutect2
- IBSP | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs144185482; called by muse, mutect2, varscan2
- ID4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 229/898 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758123800; called by muse, mutect2, varscan2
- IFITM2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 202/570 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1451585419; called by muse, mutect2
- IFNLR1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 330/695 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1286621504; called by muse, mutect2, varscan2
- IFRD2 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 145/576 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1553709621; called by muse, mutect2, varscan2
- IGFN1 | c.3436C>T p.P1146S (on ENST00000295591 / NM_001367841.1; = p.P3603S on NM_001164586.2) | Missense Mutation (SNP) | VAF 96/679 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV55187129; called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 180/586 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as rs769619522; called by muse, varscan2
- IGHV3OR16-9 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 92/410 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV61211787; called by muse, varscan2
- IGHV4-34 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs1064183; called by muse, mutect2, varscan2
- IGKV1-9 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 59/513 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs550224422; called by muse, mutect2, varscan2
- IGLV8-61 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs533312214; called by muse, mutect2, varscan2
- IGSF22 | c.2557C>T p.P853S (on ENST00000319338; = p.P954S on NM_173588.4) | Missense Mutation (SNP) | VAF 268/544 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs776997419; called by muse, mutect2, varscan2
- IGSF3 | c.2401G>A p.E801K (on ENST00000369486 / NM_001007237.3; = p.E821K on NM_001542.4) | Missense Mutation (SNP) | VAF 75/471 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as COSV59589497; called by muse, mutect2, varscan2
- IL12RB2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 24/664 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99254925; called by muse, mutect2
- IL17C | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 165/720 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs757431231; called by muse, mutect2, varscan2
- IL1RN | c.250G>A p.G84R (on ENST00000409930 / NM_173842.3; = p.G66R on NM_000577.5) | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368461190; called by muse, mutect2, varscan2
- IL31 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65476271; called by muse, mutect2, varscan2
- INAFM1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 250/1008 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1315480957; called by muse, varscan2
- ING1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 60/1296 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); catalogued as rs1486590396, COSV58169223; called by muse, mutect2
- INPP4A | c.2063G>A p.G688D (on ENST00000074304 / NM_001134224.1; = p.G649D on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/446 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50795996; called by muse, varscan2
- INPP5A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 217/465 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV61252104; called by muse, mutect2, varscan2
- INSL5 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 263/564 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV58788362; called by muse, mutect2, varscan2
- INSR | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM021104; called by muse, mutect2, varscan2
- INSYN2A | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 29/864 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.175); catalogued as rs1486536927; called by muse, mutect2
- INTS2 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1448586742; called by muse, mutect2, varscan2
- INTS5 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 31/753 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.655); catalogued as rs1454845375; called by muse, mutect2
- IQANK1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 264/1032 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1202967461; called by muse, mutect2, varscan2
- IQCF5 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 120/691 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs571907670, COSV71306835; called by muse, mutect2, varscan2
- IQCN | c.1241C>T p.T414I | Missense Mutation (SNP) | VAF 123/889 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs947031984; called by muse, mutect2, varscan2
- IRAK4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV71210502; called by muse, mutect2, varscan2
- ISLR2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 165/916 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs1317591393, COSV100679675, COSV62301543; called by muse, mutect2, varscan2
- IST1 | c.425G>A p.S142N (on ENST00000535424 / NM_001270976.1; = p.S129N on NM_014761.4) | Missense Mutation (SNP) | VAF 74/401 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.709); catalogued as COSV61709644; called by muse, mutect2, varscan2
- ITGA10 | c.1794G>A p.R598= | Splice Region (SNP) | VAF 118/363 reads (33%) | catalogued as rs782448854; called by muse, mutect2, varscan2
- ITGA2B | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV52234212; called by muse, mutect2, varscan2
- ITGA9 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 128/595 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs149951749; called by muse, mutect2, varscan2
- ITGAD | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 73/556 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs150314297; called by muse, mutect2
- ITGAE | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 83/383 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV53990884; called by muse, mutect2, varscan2
- ITGAE | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV53998720; called by muse, mutect2, varscan2
- ITGB4 | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 99/716 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52326150; called by muse, mutect2, varscan2
- ITIH5 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 143/613 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs540293946; called by muse, mutect2, varscan2
- ITPKA | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 101/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323392557, COSV53029305; called by muse, mutect2, varscan2
- ITPKB | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 163/710 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.115); catalogued as COSV55269772; called by muse, mutect2, varscan2
- ITPR3 | c.7277G>A p.S2426N | Missense Mutation (SNP) | VAF 236/534 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV65291411; called by muse, mutect2
- JAK3 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 229/868 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV71687254; called by muse, mutect2, varscan2
- JAML | c.521G>A p.G174E (on ENST00000356289 / NM_001098526.2; = p.G164E on NM_153206.3) | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as rs1173555666, COSV52629979; called by muse, mutect2, varscan2
- JHY | c.2240A>T p.E747V | Missense Mutation (SNP) | VAF 250/567 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV57076696; called by muse, mutect2, varscan2
- JMJD1C | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV101232474; called by muse, mutect2
- JMJD8 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 138/625 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778115043; called by muse, mutect2, varscan2
- JPH3 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 226/802 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248822669; called by muse, varscan2
- KANSL2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 227/513 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs371581944; called by muse, mutect2, varscan2
- KBTBD11 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 68/1412 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.285); catalogued as rs1166094342; called by muse, mutect2
- KCNA10 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 272/622 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs779800189, COSV63904481; called by muse, mutect2
- KCNF1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 96/627 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs1185412337, COSV54463557; called by muse, mutect2, varscan2
- KCNG2 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 52/1310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60266786; called by muse, mutect2
- KCNH6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 375/726 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs756068734; called by muse, mutect2, varscan2
- KCNJ11 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 128/732 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138168190, COSV104411884; called by muse, mutect2, varscan2
- KCNN3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 58/1183 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV55219206; called by muse, mutect2
- KCNQ2 | c.1681C>T p.P561S (on ENST00000359125 / NM_172107.4; = p.P533S on NM_004518.6) | Missense Mutation (SNP) | VAF 143/823 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM165060; called by muse, mutect2, varscan2
- KCNQ2 | c.1301+1G>A p.X434_splice | Splice Site (SNP) | VAF 157/1213 reads (13%) | catalogued as COSV60542928; called by muse, mutect2, varscan2
- KCNQ4 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 194/760 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1458459083; called by muse, mutect2, varscan2
- KCNU1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 160/674 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV67754565; called by muse, mutect2, varscan2
- KCNV2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 374/381 reads (98%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66057086; called by muse, mutect2, varscan2
- KDELR2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 69/904 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1009810064; called by muse, mutect2
- KDM6B | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 304/658 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs758603417; called by muse, mutect2, varscan2
- KIAA1217 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 142/702 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1401746959; called by muse, mutect2, varscan2
- KIAA1549 | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 154/974 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777698134; called by muse, mutect2, varscan2
- KIAA1755 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 126/890 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs774728826; called by muse, varscan2
- KIAA2026 | c.3683C>T p.T1228I | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1326834611; called by muse, mutect2
- KIDINS220 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 52/336 reads (15%) | catalogued as COSV56751696; called by muse, mutect2, varscan2
- KIF13B | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 78/605 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780450879; called by muse, mutect2, varscan2
- KIF15 | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749158980; called by muse, mutect2, varscan2
- KIF20B | c.4097-1G>A p.X1366_splice (on ENST00000371728 / NM_001284259.2; = p.X1326_splice on NM_016195.4) | Splice Site (SNP) | VAF 14/235 reads (6%) | catalogued as COSV53304061; called by muse, mutect2
- KIF21B | c.2731G>A p.A911T | Missense Mutation (SNP) | VAF 177/648 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs377123925, COSV59754573; called by muse, mutect2, varscan2
- KIF3A | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1388938837; called by muse, mutect2, varscan2
- KIFBP | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1430252870; called by muse, mutect2, varscan2
- KIFC3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 291/1122 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.994); catalogued as rs1555623884; called by muse, mutect2, varscan2
- KIT | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 166/772 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853357; called by muse, mutect2, varscan2
- KLHL6 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 113/598 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776834054; called by muse, mutect2, varscan2
- KLHL8 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 139/582 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV56748674; called by muse, varscan2
- KLK14 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 106/537 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.438); catalogued as rs1371707752; called by muse, mutect2, varscan2
- KMT2B | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 203/447 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs374066966; called by muse, mutect2, varscan2
- KMT2B | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as rs374176981; called by muse, mutect2, varscan2
- KMT2B | c.6686C>T p.P2229L | Missense Mutation (SNP) | VAF 68/427 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.086); catalogued as rs1458974861; called by muse, mutect2, varscan2
- KMT2C | c.12430C>T p.L4144F | Missense Mutation (SNP) | VAF 84/948 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as rs148110224, COSV51502711; called by muse, mutect2
- KMT2D | c.10606C>T p.R3536C | Missense Mutation (SNP) | VAF 323/659 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD114134, COSV56428871; called by muse, mutect2, varscan2
- KPNA3 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as rs1043015; called by muse, mutect2, varscan2
- KPNA6 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 79/487 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV65361760; called by muse, mutect2, varscan2
- KRT16 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 324/761 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs765533099; called by muse, mutect2, varscan2
- KRT2 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 164/684 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as rs201743641; called by muse, mutect2, varscan2
- KRT32 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 167/361 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs933069187; called by muse, mutect2, varscan2
- KRT6A | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 211/1085 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1308335675, COSV58105048; called by muse, mutect2, varscan2
- KRT6B | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 283/610 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as rs1360812915; called by muse, mutect2, varscan2
- KRT72 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 30/830 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1258616553, COSV53374170; called by muse, mutect2
- KRT73 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.437); catalogued as rs1393558390; called by muse, mutect2
- KRT76 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 149/301 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs748842366, COSV60121165; called by muse, varscan2
- KRT85 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 176/415 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57736881; called by muse, mutect2, varscan2
- KRTAP13-3 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 126/634 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV61878969; called by muse, mutect2, varscan2
- KRTAP16-1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 212/856 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1384179132; called by muse, mutect2, varscan2
- KRTAP21-3 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 86/409 reads (21%) | PolyPhen probably damaging (0.97); catalogued as COSV71480750; called by muse, mutect2, varscan2
- KRTAP24-1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 96/506 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs759054217; called by muse, mutect2, varscan2
- KRTAP24-1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 272/527 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as rs746549598; called by muse, mutect2, varscan2
- KRTAP27-1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 142/655 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs1054873176; called by muse, varscan2
- KRTAP4-11 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 406/1110 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs778010463, COSV101194925; called by muse, mutect2, varscan2
- L1CAM | c.2289G>A p.W763* | Nonsense Mutation (SNP) | VAF 28/580 reads (5%) | catalogued as rs1557091014; called by muse, mutect2
- LACTB | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 320/1195 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.035); catalogued as rs1334088859, COSV99978999; called by muse, mutect2, varscan2
- LAG3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 175/1070 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1477455682; called by muse, mutect2, varscan2
- LAMA2 | c.9068G>A p.G3023E | Missense Mutation (SNP) | VAF 90/447 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352024692; called by muse, mutect2, varscan2
- LAMA5 | c.7916C>T p.A2639V | Missense Mutation (SNP) | VAF 175/1276 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV99441052; called by muse, mutect2, varscan2
- LAMB2 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 80/468 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as rs1451872451, COSV100565482; called by muse, mutect2, varscan2
- LAMB4 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs753900276, COSV99225004; called by muse, mutect2, varscan2
- LAMC2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.941); catalogued as rs367738116; called by muse, mutect2, varscan2
- LAMP1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 200/666 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs1312058594; called by muse, mutect2, varscan2
- LBX1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 242/980 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1178332623; called by muse, varscan2
- LCAT | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV50455931; called by muse, mutect2, varscan2
- LCOR | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 183/438 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs774593262; called by muse, mutect2, varscan2
- LCOR | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs1244894429; called by muse, mutect2, varscan2
- LCTL | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.304); catalogued as rs370655423; called by muse, mutect2, varscan2
- LDHC | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 82/455 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55005175; called by muse, mutect2, varscan2
- LDHD | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 225/962 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779364388; called by muse, mutect2, varscan2
- LENG8 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 198/793 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs1237501166; called by muse, mutect2, varscan2
- LGR5 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200272164, COSV57003493; called by muse, mutect2, varscan2
- LGR6 | c.1769G>A p.G590E (on ENST00000367278 / NM_001017403.1; = p.G538E on NM_021636.3) | Missense Mutation (SNP) | VAF 332/708 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as rs1243165603; called by muse, mutect2
- LHX9 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 317/676 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV61331241; called by muse, mutect2, varscan2
- LIF | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs771820759; called by muse, mutect2, varscan2
- LILRA2 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 344/813 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV99252942; called by muse, varscan2
- LILRA4 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 42/1192 reads (4%) | catalogued as rs778935663, COSV52496396; called by muse, mutect2
- LILRB5 | c.1355G>A p.S452N (on ENST00000449561 / NM_001081442.3; = p.S451N on NM_006840.5) | Missense Mutation (SNP) | VAF 90/726 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as COSV100300694; called by muse, mutect2, varscan2
- LIM2 | c.278C>T p.S93F (on ENST00000596399 / NM_001161748.2; = p.S135F on NM_030657.4) | Missense Mutation (SNP) | VAF 171/723 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs1267227291, COSV55741323; called by muse, mutect2, varscan2
- LIMD1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 30/847 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs896057068; called by muse, mutect2
- LIN7A | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV54023381; called by muse, mutect2, varscan2
- LMBR1L | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 63/512 reads (12%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.993); catalogued as rs768242268, COSV57269276; called by muse, mutect2, varscan2
- LMNB1 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 88/502 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV54400413; called by mutect2, varscan2
- LMO7 | c.620G>A p.G207D (on ENST00000357063; = p.G222D on NM_005358.5) | Missense Mutation (SNP) | VAF 195/433 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309512704, COSV100414024; called by muse, mutect2, varscan2
- LMOD1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 201/737 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV66172842; called by muse, varscan2
6,361 further variants in this file (3,719 protein-altering or splice-affecting, 2,342 silent, 300 other) are not listed here.
